CCDI case PBBURU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other endocrine glands and related structures.
https://portal.gdc.cancer.gov/cases/f93044f5-4fca-44cb-acc2-2b03661238f0

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Pineal gland; Age at diagnosis: 4.8 years (1,765 days).

Biospecimens (2 samples)
- Sample 0DJE38: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DJE3E: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
